Somatic mutation profile of tumor specimen TCGA-Q3-A5QY-01A (aliquot TCGA-Q3-A5QY-01A-12D-A32N-08) from TCGA case TCGA-Q3-A5QY, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 58.3 years (21,277 days).
Specimen TCGA-Q3-A5QY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d2372699-10a4-48d1-8543-a561dd7a520b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-Q3-A5QY-10A (Blood Derived Normal), aliquot TCGA-Q3-A5QY-10A-01D-A32N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a7db1e54-a4e8-4830-9f1e-8d17cb8258f2

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- UBR3 | c.3584C>T p.A1195V | Missense Mutation (SNP) | VAF 24/652 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99775161; called by muse, mutect2
- ZNF780A | c.1089C>A p.C363* | Nonsense Mutation (SNP) | VAF 15/495 reads (3%) | called by muse, mutect2
